Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-A8QR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-A8QR-01A (Primary Tumor).

ACCT#: [REDACTED] DOB: [REDACTED]

Specimen #:

Date Obtained:

Date Received:

Dr.:

Date Printed:

CLINICAL HISTORY:
STUDY

SPECIMEN/PROCEDURE:

1. CERVIX - BIOPSY

ICD-O-3
Carcinoma, squamous cell, large cell
keratinizing NOS 8071/3
Site: Cervix NOS C53.9
JN 6/6/14

IMPRESSION:

CERVIX, 12 O'CLOCK, BIOPSY:

- . Invasive squamous cell carcinoma, large cell keratinizing type, poorly differentiated.
- . Severe dysplasia with glandular involvement.

Dictated by: [REDACTED]

Entered: [REDACTED]

GROSS DESCRIPTION:

This case is part of the [REDACTED] study.

Received in formalin, labeled "cervical biopsy at 12:00" and with the patient's name, is an irregular unoriented portion of shaggy pale tan to tan rubbery tissue, 2.5 x 1.3 x 0.8 cm. The specimen is serially sectioned at close intervals, and entirely submitted in two cassettes.

Dictated by:

Entered:

CPT Codes:

CERVICAL BIOPSY (1)/88305

ICD9 Codes:

180.9

Electronically Signed by: [REDACTED]

Patient: [REDACTED] Age/Sex: F Acct#: [REDACTED] Unit: [REDACTED]

Source: NCI Genomic Data Commons file 4f7f0b75-e099-45ff-b77d-cdd9b7173a81 (TCGA-ZJ-A8QR.0C8716BD-1A48-4392-9F40-6A5C04FA8004.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).